Gene-level copy-number profile of tumor specimen TCGA-30-1892-01A from TCGA case TCGA-30-1892, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.7 years (19,256 days).
Specimen TCGA-30-1892-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e4d8afcf-21af-4406-bc25-ff15f9c85107.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1892-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d58fdf8-906a-4ef1-88fe-f71210030c9e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 828; copy number 2: 11,994; copy number 3: 32,149; copy number 4: 13,475; copy number 5: 243; copy number 6: 252; copy number 7: 1; copy number 8: 343; copy number 11: 535.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1892-01): tumor purity 0.64, ploidy 3.22, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 879 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:90,791,741–145,066,685, 878 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).
- chr20:48,821,688–48,849,458, 1 gene, copy number 7: AL133342.1.

Autosomal genes at a single copy (total copy number 1): 828. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
